Somatic mutation profile of tumor specimen TCGA-YZ-A983-01A (aliquot TCGA-YZ-A983-01A-11D-A39W-08) from TCGA case TCGA-YZ-A983, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.4 years (18,769 days).
Specimen TCGA-YZ-A983-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ded57474-329f-4900-85ab-7e5c14a1d4ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YZ-A983-10B (Blood Derived Normal), aliquot TCGA-YZ-A983-10B-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4a17934-7bce-45c8-8be6-fd2ed4910e9d

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 29/68 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRT79 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs775879705, COSV57938097, COSV57938701; called by muse, mutect2, varscan2
- LRP1B | c.12197T>C p.V4066A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs1160561610; called by muse, varscan2
- PRRC2B | c.3382C>T p.R1128W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559310957, COSV61942815; called by muse, mutect2, varscan2
- SNAP91 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs764466153, COSV99536847; called by muse, mutect2, varscan2
- VASH2 | c.580G>T p.V194F (on ENST00000517399 / NM_001301056.2; = p.V150F on NM_024749.5) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55118238; called by muse, mutect2, varscan2
- CD4 | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERMARD | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA4 | c.5609A>C p.H1870P | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MPP3 | c.1673T>G p.L558R | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PCDHGB1 | c.327C>A p.N109K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.158); called by muse, mutect2
- PCK2 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PROSER1 | c.1871A>G p.H624R | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TBX6 | c.771C>G p.I257M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM39A | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- FES | c.954T>G p.A318= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- GABBR2 | c.612C>T p.D204= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs142025089; called by muse, mutect2, varscan2
- OPRM1 | c.588C>T p.L196= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV57677335; called by muse, mutect2, varscan2
- PTPMT1 | c.276C>T p.V92= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1428676655, COSV58597688; called by muse, mutect2, varscan2
- PTPRD | c.5412G>A p.Q1804= | Silent (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
